Somatic mutation profile of tumor specimen TCGA-95-A4VP-01A (aliquot TCGA-95-A4VP-01A-21D-A25L-08) from TCGA case TCGA-95-A4VP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.1 years (24,130 days).
Specimen TCGA-95-A4VP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9c84da-741e-4647-bc34-a17b4e637f0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-A4VP-10A (Blood Derived Normal), aliquot TCGA-95-A4VP-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/597cdc66-17b0-496a-b51d-778df192aca7

The open-access MAF lists 130 somatic variants for this specimen: 96 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 32, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, RNA 2, Splice Region 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM991156, COSV58820621, COSV58820976, COSV99045288; called by muse, mutect2
- ANGPTL7 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816802; called by muse, mutect2, varscan2
- AOC1 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100711075; called by muse, mutect2, varscan2
- ASIC1 | c.885G>T p.M295I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV57318881, COSV99948305; called by muse, mutect2, varscan2
- ATAD5 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430303; called by muse, mutect2, varscan2
- ATM | c.8082_8084del p.G2695del | In Frame Del (DEL) | VAF 22/75 reads (29%) | catalogued as rs1565540828; called by pindel, varscan2
- BCL9 | c.2450T>C p.M817T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs781846437, COSV99326050; called by muse, mutect2, varscan2
- BRMS1L | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.81); catalogued as COSV99396890; called by muse, mutect2
- C2orf78 | c.2040G>T p.E680D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV101280890; called by muse, mutect2, varscan2
- CACHD1 | c.3593G>T p.S1198I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99263576; called by muse, mutect2, varscan2
- CFAP46 | c.8071G>A p.G2691S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as rs199903602, COSV99585776; called by muse, mutect2, varscan2
- CHRNB3 | c.53-2A>T p.X18_splice | Splice Site (SNP) | VAF 32/135 reads (24%) | catalogued as COSV99251584; called by muse, mutect2, varscan2
- CKAP2L | c.1759-2A>T p.X587_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | catalogued as COSV100198839; called by muse, mutect2, varscan2
- CNTN5 | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99682553; called by muse, mutect2, varscan2
- COL25A1 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211723; called by muse, mutect2, varscan2
- CPN1 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100962765; called by muse, mutect2, varscan2
- DEPDC1 | c.1142A>T p.Q381L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100920529; called by muse, mutect2, varscan2
- DNAH2 | c.2784G>A p.V928= | Splice Region (SNP) | VAF 39/274 reads (14%) | catalogued as COSV101209659, COSV66722953; called by muse, mutect2, varscan2
- DOCK10 | c.4615T>A p.F1539I | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99292249; called by muse, mutect2
- ECT2L | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587778245, COSV100872234; ClinVar: not provided; called by muse, mutect2, varscan2
- EMD | c.345G>T p.R115S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV63962056; called by muse, mutect2, varscan2
- ENTPD6 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737206; called by muse, mutect2, varscan2
- FAN1 | c.2905C>A p.R969S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as COSV100756129; called by muse, mutect2, varscan2
- FLG | c.11293A>G p.R3765G | Missense Mutation (SNP) | VAF 36/837 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs746970097, COSV64238761; called by muse, mutect2
- FLG | c.4408C>T p.H1470Y | Missense Mutation (SNP) | VAF 96/530 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV100911450, COSV100912442; called by muse, varscan2
- FRG2C | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1327015748; called by muse, mutect2
- FSD1 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV99697090; called by muse, mutect2, varscan2
- GAA | c.566G>T p.R189M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV100163605; called by muse, mutect2
- GALNT2 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100795930; called by muse, mutect2, varscan2
- GP2 | c.1211C>A p.T404N (on ENST00000381362 / NM_001007240.3; = p.T401N on NM_001502.4) | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221696; called by muse, mutect2, varscan2
- GRID1 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100027169; called by muse, mutect2, varscan2
- HECTD4 | c.8489C>A p.P2830H | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101108440; called by muse, mutect2
- HLA-DOA | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57715975; called by muse, mutect2, varscan2
- HYDIN | c.11087C>A p.P3696Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101159065; called by muse, mutect2, varscan2
- JADE2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99253729; called by muse, mutect2, varscan2
- KRT37 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as COSV99845800; called by muse, mutect2
- KRTAP27-1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1487554397, COSV101239802; called by muse, mutect2, varscan2
- KRTAP5-3 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101294531; called by muse, mutect2, varscan2
- LAMA4 | c.2068G>T p.A690S (on ENST00000230538 / NM_001105206.3; = p.A683S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV100039817; called by muse, mutect2, varscan2
- LARP6 | c.412-1G>T p.X138_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100151140; called by muse, mutect2
- LBP | c.257G>C p.C86S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV54144000, COSV99461462; called by muse, mutect2
- LRRC3B | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV101186090; called by muse, mutect2, varscan2
- MELTF | c.1826C>A p.A609D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1475649028, COSV99586732; called by muse, mutect2, varscan2
- MGAT1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV100286613, COSV57133101; called by muse, mutect2
- MINPP1 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100916802; called by muse, mutect2, varscan2
- MLH1 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV51623182, COSV51625392; called by muse, mutect2, varscan2
- MRPL44 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1296738315, COSV99285367; called by muse, mutect2, varscan2
- MXRA5 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1308508075, COSV99479859; called by mutect2, varscan2
- MYH2 | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as COSV55439827; called by muse, mutect2
- MYOCD | c.2623A>T p.S875C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100591590; called by muse, mutect2, varscan2
- NCR2 | c.434T>C p.L145P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs151035226; called by muse, mutect2, varscan2
- NDE1 | c.964G>A p.A322T (on ENST00000577101; = p.S294N on NM_017668.3) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100707411; called by muse, mutect2, varscan2
- NLRP7 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV100053504; called by muse, mutect2, varscan2
- NLRP7 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.114); catalogued as COSV100053505; called by muse, mutect2, varscan2
- OBSCN | c.6257T>G p.V2086G | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1428123607, COSV99486124; called by muse, mutect2, varscan2
- OGT | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV101035683; called by muse, mutect2, varscan2
- OR2L2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs373354734, COSV63547472; called by muse, mutect2, varscan2
- OR4P4 | c.163C>A p.Q55K | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV100111902; called by muse, mutect2, varscan2
- OTOP3 | c.911A>T p.H304L | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100173134; called by muse, mutect2, varscan2
- PCDHB10 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.111); catalogued as COSV99505201; called by muse, mutect2, varscan2
- PEAK1 | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56939179; called by muse, mutect2, varscan2
- PFKFB3 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100432495; called by muse, mutect2, varscan2
- PKD1L1 | c.6499T>C p.W2167R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99221770; called by muse, mutect2, varscan2
- PNN | c.114G>A p.R38= | Splice Region (SNP) | VAF 77/121 reads (64%) | catalogued as rs1173255605, COSV99397464; called by muse, mutect2, varscan2
- PRRX1 | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99510525; called by muse, mutect2, varscan2
- REG3G | c.124A>T p.K42* | Nonsense Mutation (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99709785; called by muse, mutect2, varscan2
- RNF10 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.092); catalogued as COSV100379087, COSV58045534; called by muse, mutect2, varscan2
- RRH | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs761381979, COSV100496214; called by muse, mutect2
- RYR2 | c.14566G>T p.V4856F | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100773355, COSV63710173; called by muse, mutect2, varscan2
- RYR3 | c.5224G>T p.D1742Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66789590; called by muse, mutect2, varscan2
- SACS | c.12990G>T p.R4330S | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101207857; called by muse, mutect2, varscan2
- SCN3A | c.4767G>C p.W1589C | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51810448, COSV99328961; called by muse, mutect2, varscan2
- SLC2A4 | c.902C>G p.S301C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99142866; called by muse, mutect2
- SLC44A4 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99999390; called by muse, mutect2, varscan2
- SLC45A2 | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.152); catalogued as COSV99673335; called by muse, mutect2, varscan2
- SPTBN5 | c.4796A>G p.E1599G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100312442; called by muse, mutect2, varscan2
- STYX | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100648343, COSV100648357; called by muse, mutect2, varscan2
- SYNE1 | c.6955T>A p.W2319R (on ENST00000367255 / NM_182961.4; = p.W2326R on NM_033071.3) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as COSV99584038; called by muse, mutect2, varscan2
- SYT9 | c.990G>T p.L330F | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100609522; called by muse, mutect2, varscan2
- TBCE | c.566A>T p.Q189L (on ENST00000366601; = p.Q252L on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100783312; called by muse, mutect2, varscan2
- TCAP | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504427, CM062009, COSV54094138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THSD1 | c.1931A>G p.H644R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.424); catalogued as rs1283360368, COSV51626512; called by muse, mutect2
- TNN | c.1092G>C p.E364D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV99511907, COSV99513365; called by mutect2, varscan2
- TSPAN8 | c.566T>A p.V189D | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99922771; called by muse, mutect2, varscan2
- UBR5 | c.4196A>T p.D1399V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99642725; called by muse, mutect2, varscan2
- UGT1A10 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100762703; called by muse, mutect2
- VSNL1 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99723437; called by muse, mutect2
- ZFHX4 | c.7784G>A p.G2595E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99266796; called by muse, mutect2, varscan2
- ZFHX4 | c.8755T>A p.F2919I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV99269142; called by muse, mutect2, varscan2
- ZW10 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99563003; called by muse, mutect2, varscan2
- DSCC1 | c.293del p.C98Lfs*7 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- PAOX | c.1251_1252insAC p.A418Tfs*109 | Frame Shift Ins (INS) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- PRDM5 | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2
- RASAL2 | c.661del p.L221Ffs*27 | Frame Shift Del (DEL) | VAF 30/177 reads (17%) | called by mutect2, pindel, varscan2
- TRAJ23 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 34/86 reads (40%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ASB5 | c.801G>A p.L267= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV99642244; called by muse, mutect2
- CACNA1B | c.4488C>A p.P1496= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs201657859, COSV53127534, COSV99500572; called by muse, mutect2
- CHD5 | c.2928C>A p.G976= | Silent (SNP) | VAF 58/207 reads (28%) | catalogued as COSV99315523; called by muse, mutect2, varscan2
- CHD7 | c.7563A>G p.G2521= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV101418596; called by muse, mutect2, varscan2
- CMYA5 | c.4434A>G p.S1478= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV101484457; called by muse, mutect2, varscan2
- CPSF6 | c.864A>G p.P288= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV57015355; called by muse, mutect2, varscan2
- DCAF4L2 | c.999C>A p.G333= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV60479369, COSV60482998; called by muse, mutect2, varscan2
- DNAH5 | c.11544G>T p.L3848= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV99455603; called by muse, mutect2, varscan2
- DNAH5 | c.6663A>G p.E2221= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as COSV99455607; called by muse, mutect2, varscan2
- FLI1 | c.882C>T p.S294= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1448246958, COSV55643944; called by muse, mutect2, varscan2
- FMN2 | c.2616C>A p.G872= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV100147827; called by muse, mutect2, varscan2
- KIF2B | c.510C>A p.I170= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV99276504; called by muse, mutect2, varscan2
- LBP | c.969C>T p.P323= | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as COSV99461465; called by muse, mutect2
- LUZP2 | c.537T>A p.T179= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100421761; called by muse, mutect2, varscan2
- MTTP | c.591G>T p.A197= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99645730; called by muse, mutect2, varscan2
- MYH2 | c.1917C>A p.A639= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99821216; called by muse, mutect2, varscan2
- NEB | c.14091T>C p.N4697= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99429050; called by muse, mutect2
- NSUN6 | c.849G>T p.G283= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV101046066; called by muse, mutect2, varscan2
- OR10J3 | c.918G>C p.G306= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV100171937; called by muse, mutect2, varscan2
- OR2D3 | c.699T>G p.S233= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99550039; called by muse, mutect2
- OVCH1 | c.921A>G p.K307= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs779517580, COSV100549384, COSV58962796; called by muse, mutect2, varscan2
- PCDHB5 | c.1296C>T p.T432= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs1265120526, COSV99169763; called by muse, mutect2, varscan2
- PDC | c.192A>T p.S64= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV100414898; called by muse, mutect2, varscan2
- PDCL2 | c.48T>C p.D16= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99824226; called by muse, mutect2, varscan2
- SETX | c.7761A>T p.I2587= | Silent (SNP) | VAF 31/164 reads (19%) | catalogued as COSV99811293; called by muse, mutect2, varscan2
- SLC6A17 | c.216C>A p.A72= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100521602; called by mutect2, varscan2
- STMN2 | c.240C>A p.S80= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV99627055; called by muse, mutect2, varscan2
- TCHH | c.5235C>T p.R1745= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- UNC5D | c.2400C>A p.T800= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV54826575; called by muse, mutect2, varscan2
- ZFHX4 | c.5826C>T p.N1942= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99269136; called by muse, mutect2, varscan2
- ZFHX4 | c.8754C>A p.P2918= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99269139; called by muse, mutect2, varscan2
- ZNF804B | c.1228A>C p.R410= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV60853201; called by muse, mutect2, varscan2
- AL590867.2 | n.21G>T | RNA (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- MIR758 | n.24C>A | RNA (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
